MMRF case MMRF_2377 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4f1712d0-6b02-42bf-a99b-ff870c148d60

Demographics
Sex at birth: male; Race: other; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.7 years (22,910 days); ISS stage: II; Days to last known disease status: 734 days (2.0 years); Days to last follow up: 734 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 4 (ECOG 0): M Protein 7.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 85.1 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.1 mmol/L; Albumin 30 g/L; Total Protein 12 g/dL; Glucose 4.9 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 83 (ECOG 0): Hemoglobin 9.49 mmol/L; Leukocytes 4.79 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 6.66 mmol/L.
- Day 176 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 8.02 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 6.99 mmol/L.
- Day 288 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 6.6 mmol/L.
- Day 372 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.25 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 5.89 mmol/L.
- Day 454 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.5 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 1.87 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 7.26 mmol/L.
- Day 538 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 5.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.67 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 2.1 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 4.68 mmol/L.
- Day 650 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.04 mg/dL; Immunoglobulin G 17.5 g/L; Immunoglobulin A 2.57 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.8 g/dL; Glucose 5.72 mmol/L.
- Day 734 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.13 mg/dL; Immunoglobulin G 16.2 g/L; Immunoglobulin A 2.7 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day 4: Weight: 68 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2377_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 4 days.
- Sample MMRF_2377_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 4 days.
